MMRF case MMRF_1186 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e04417a0-1644-410d-b771-d5d097500a49

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.1 years (24,867 days); ISS stage: I; Days to last known disease status: 1,649 days (4.5 years); Days to last follow up: 1,649 days (4.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 215 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 234 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 312 days; Days to treatment end: 979 days (2.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,264 days (3.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.77 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.77 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 6.6 mmol/L.
- Day 53 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 6.62 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 39.8 g/L; Total Protein 5.9 g/dL; Glucose 6.66 mmol/L.
- Day 193 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 5.46 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.6 ×10⁹/L; Platelets 146 ×10⁹/L; Albumin 39.9 g/L; Total Protein 6.1 g/dL.
- Day 255 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 6.89 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.67 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 65.4 µmol/L; Albumin 40.7 g/L; Total Protein 5.7 g/dL.
- Day 312 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Hemoglobin 8.18 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 65.4 µmol/L; Albumin 40.7 g/L; Total Protein 5.7 g/dL.
- Day 444 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.282 mg/dL; Immunoglobulin G 7.81 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.32 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 550 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 7.26 mmol/L.
- Day 633 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 7.68 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.86 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 6.22 mmol/L.
- Day 717 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 7.28 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.99 mmol/L.
- Day 781 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 7.28 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 7.81 mmol/L.
- Day 865 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 8.8 mmol/L.
- Day 955 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 8.75 mmol/L.
- Day 1,077 (ECOG 2): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 8.89 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.05 mmol/L.
- Day 1,138 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 9.96 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 8.03 mmol/L.
- Day 1,228 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 8.11 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.46 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 6.27 mmol/L.
- Day 1,320: M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 8.6 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 6.22 mmol/L.
- Day 1,448 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 7.3 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.56 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 7.04 mmol/L.
- Day 1,551 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Immunoglobulin G 8.44 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.67 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6.71 mmol/L.
- Day 1,649: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 7.26 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Glucose 7.15 mmol/L.

Other clinical attributes
- Day -23: Weight: 75 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1186_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,228 days (3.4 years).
- Sample MMRF_1186_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1,228 days (3.4 years).
